Somatic mutation profile of tumor specimen TCGA-AA-3524-01A (aliquot TCGA-AA-3524-01A-02D-1953-10) from TCGA case TCGA-AA-3524, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage II; Age at diagnosis: 85.4 years (31,197 days).
Specimen TCGA-AA-3524-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b5488a1-c246-40fb-bcb8-4799d90d65c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3524-11A (Solid Tissue Normal), aliquot TCGA-AA-3524-11A-01D-1554-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d16ef357-5bbe-4571-8913-481ec10913d2

The open-access MAF lists 14 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 12, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C12orf40 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 102/375 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV100209955; called by muse, mutect2, varscan2
- COL24A1 | c.4303G>A p.G1435S | Missense Mutation (SNP) | VAF 156/436 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs565761327, COSV100993179; called by muse, mutect2, varscan2
- COLEC12 | c.1772C>T p.P591L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as COSV101232043; called by muse, mutect2, varscan2
- DNAH7 | c.11843A>G p.K3948R | Missense Mutation (SNP) | VAF 99/268 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.831); catalogued as rs374466394; called by muse, mutect2, varscan2
- DNAH7 | c.10961C>T p.T3654M | Missense Mutation (SNP) | VAF 128/343 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as rs373822825; called by muse, mutect2, varscan2
- KIDINS220 | c.2150C>T p.S717L | Missense Mutation (SNP) | VAF 111/375 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as rs144492511; called by muse, mutect2, varscan2
- MARF1 | c.4966C>T p.R1656C | Missense Mutation (SNP) | VAF 79/246 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.54); catalogued as rs776983879, COSV100705791; called by muse, mutect2, varscan2
- SIGLEC6 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.599); catalogued as COSV58431638; called by muse, mutect2, varscan2
- STAB1 | c.446A>G p.E149G | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV100401580; called by muse, mutect2, varscan2
- STEAP3 | c.625C>A p.L209I | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs991031822, COSV100713274; called by muse, mutect2, varscan2
- TRO | c.3301G>A p.G1101S | Missense Mutation (SNP) | VAF 48/69 reads (70%) | SIFT tolerated (0.19); PolyPhen benign (0.313); catalogued as rs773140897, COSV99436029; called by muse, mutect2, varscan2
- ZNF335 | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 105/442 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs755983006, COSV100532902; called by muse, mutect2, varscan2
- SOX9 | c.322_325del p.P108* | Frame Shift Del (DEL) | VAF 52/70 reads (74%) | called by mutect2, pindel, varscan2
- AUTS2 | c.3105C>T p.N1035= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV100716207; called by muse, mutect2, varscan2
